Surgical pathology report (de-identified scan), TCGA case TCGA-WH-A86K, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Greenville Health System, specimen TCGA-WH-A86K-01A (Primary Tumor).

PATHOLOGY EXAMINATION

COLLECTED

CLIENT:

ADDITIONAL:

NO ADDITIONAL PHYSICIANS

COPY TO/NOTES:

Page 1 of 5

SPECIMEN(S) RECEIVED:

A: Right frontal brain tumor

FINAL PATHOLOGIC DIAGNOSIS:

CASE SENT IN CONSULTATION TO [REDACTED] SEE COMPLETE REPORT ATTACHED WITH

DIAGNOSIS OF:

"BRAIN, RIGHT FRONTAL LOBE MASS, BIOPSY [REDACTED]"

INFILTRATIVE GLIOMA WITH FEATURES MOST CONSISTENT WITH LOW GRADE ASTROCYTOMA
(WHO GRADE II). SEE COMMENT."

ELECTRONICALLY SIGNED OUT

FROZEN SECTION DIAGNOSIS:

GLIAL NEOPLASM, FAVOR GRADE II-III. Discussed with [REDACTED]

GROSS DESCRIPTION:

[REDACTED] Right frontal brain tumor: The specimen is received fresh for frozen section evaluation labeled [REDACTED] right frontal brain tumor". The specimen is received fresh for frozen section evaluation labeled [REDACTED] right frontal brain tumor", and consists of multiple fragments of soft tan tissue measuring 2.5 x 1.5 x 1 cm. Squash preparations x2 are obtained. Representative sections of the specimen are frozen in AFS1 cryoblock, frozen section remnant as A1 under the direction of [REDACTED]

Three portions of the specimen are utilized for tissue banking, and the remaining portion of specimen is submitted for permanent section in cassette A2. [REDACTED]

ICD O-3

Astrocytoma, grade II 940013
Site: ^{site} Brain, supratentorial NOS C71.0
^{path} B Brain, frontal lobe C71.1
4/4/14

Review	10/16/13	Yes	No
ICD/A Discrepancy			
Primary Malignancy History			
Primary/Synchronous Primary/Secondary			

Source: NCI Genomic Data Commons file 3675227a-e438-4dbf-8179-b51d3c1f978a (TCGA-WH-A86K.BA54C0C4-01A6-4764-ABEC-F38C6F89F1BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).